Somatic mutation profile of tumor specimen TCGA-YL-A9WI-01A (aliquot TCGA-YL-A9WI-01A-11D-A377-08) from TCGA case TCGA-YL-A9WI, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.5 years (23,184 days).
Specimen TCGA-YL-A9WI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ef107d0-9b1a-4630-8e1e-6ed3a29a087a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A9WI-10A (Blood Derived Normal), aliquot TCGA-YL-A9WI-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a83bd742-6aa7-47cd-8733-36a5a1894675

The open-access MAF lists 46 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 10, Splice Region 2, Frame Shift Del 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 19/38 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1204900727, COSV51643222, COSV51643797; called by muse, mutect2, varscan2
- ABCA7 | c.2553G>C p.L851= | Splice Region (SNP) | VAF 10/94 reads (11%) | catalogued as COSV99566745; called by muse, mutect2, varscan2
- CETP | c.422A>T p.Q141L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.143); catalogued as COSV99570365; called by muse, mutect2, varscan2
- DCLK3 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs1226623277, COSV101374158; called by muse, mutect2, varscan2
- DPM1 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV99724522; called by muse, mutect2, varscan2
- GLI3 | c.1591T>C p.Y531H | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101230082; called by muse, mutect2
- GLP1R | c.1018A>C p.M340L | Missense Mutation (SNP) | VAF 64/92 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV100952761; called by muse, mutect2, varscan2
- KCNA1 | c.23A>T p.N8I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV101230386; called by muse, mutect2, varscan2
- KLK4 | c.120C>G p.H40Q | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV100133732, COSV60677320; called by muse, mutect2, varscan2
- METAP2 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.26); catalogued as COSV99705015; called by muse, varscan2
- MIPOL1 | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV59385162; called by muse, mutect2, varscan2
- MTUS2 | c.2386G>A p.A796T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); catalogued as rs556525596, COSV101462059; called by muse, mutect2, varscan2
- NCAN | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746051760, COSV99388461; called by muse, mutect2, varscan2
- NCOA1 | c.1548C>G p.S516R | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV56045621, COSV56051387, COSV99947196; called by muse, mutect2, varscan2
- OR6K3 | c.284C>A p.P95H (on ENST00000368146; = p.P79H on NM_001005327.2) | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316215692, COSV100933902; called by muse, mutect2, varscan2
- PLAA | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as rs376535885, COSV101263583; called by muse, mutect2, varscan2
- PTPN23 | c.87T>C p.F29= | Splice Region (SNP) | VAF 10/101 reads (10%) | catalogued as COSV99651101; called by muse, mutect2, varscan2
- RDH16 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as COSV100660182; called by muse, mutect2, varscan2
- RPRD2 | c.3893C>G p.P1298R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as rs1472071763, COSV100955411; called by muse, varscan2
- RPRD2 | c.3895G>C p.V1299L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100955414; called by muse, varscan2
- SART3 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs776249648, COSV57211326; called by muse, mutect2, varscan2
- SBF2 | c.1402C>A p.P468T | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV99815964; called by muse, mutect2, varscan2
- SCAF1 | c.2456C>T p.S819F | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100862316; called by muse, mutect2, varscan2
- SPTA1 | c.985A>G p.K329E | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as rs754344751, COSV100935660; called by muse, mutect2, varscan2
- STPG4 | c.221A>C p.N74T | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV99681466; called by muse, mutect2, varscan2
- TNNT3 | c.335C>A p.A112E (on ENST00000397301 / NM_001367846.1; = p.A101E on NM_006757.4) | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs377446757; called by muse, mutect2, varscan2
- TOP3A | c.2253A>T p.R751S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100329343; called by muse, mutect2, varscan2
- TSC2 | c.4699G>C p.G1567R | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99239182; called by muse, mutect2, varscan2
- TTC30A | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); catalogued as COSV100826210; called by muse, mutect2, varscan2
- WDR75 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100134489; called by muse, mutect2, varscan2
- XIRP2 | c.9136C>G p.L3046V (on ENST00000628543; = p.L3221V on NM_152381.6) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs768081610, COSV99748145; called by muse, mutect2, varscan2
- ZNF146 | c.241T>C p.F81L | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100757782; called by muse, mutect2
- ZNF318 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs549275559, COSV58938032; called by muse, mutect2, varscan2
- APC | c.3936_3942del p.T1313Qfs*6 | Frame Shift Del (DEL) | VAF 14/23 reads (61%) | called by mutect2, varscan2
- SMC5 | c.2103_2104del p.K701Nfs*28 | Frame Shift Del (DEL) | VAF 23/62 reads (37%) | called by mutect2, pindel, varscan2
- AVPR1A | c.288C>A p.A96= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100146921; called by muse, mutect2, varscan2
- IL18RAP | c.1170G>A p.L390= | Silent (SNP) | VAF 69/151 reads (46%) | catalogued as COSV99962271, COSV99962460; called by muse, mutect2, varscan2
- LRRC43 | c.228C>T p.P76= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs767289151, COSV100337005; called by muse, mutect2, varscan2
- MAGEC1 | c.3036C>A p.T1012= | Silent (SNP) | VAF 53/60 reads (88%) | catalogued as COSV99596686; called by muse, mutect2, varscan2
- OR6K3 | c.285C>T p.P95= (on ENST00000368146; = p.P79= on NM_001005327.2) | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as COSV100933900, COSV63745413; called by muse, mutect2, varscan2
- PIP4K2C | c.942C>T p.S314= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV100533821; called by muse, mutect2, varscan2
- RANBP6 | c.27G>T p.V9= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs1310176626, COSV99424466; called by muse, mutect2, varscan2
- RPRD2 | c.3894T>A p.P1298= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100955412; called by muse, varscan2
- TEX15 | c.6936A>G p.R2312= (on ENST00000256246; = p.R2695= on NM_001350162.2) | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as COSV99822237; called by muse, mutect2, varscan2
- ZNF827 | c.2460C>T p.D820= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as rs565610282, COSV101061831; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 4/22 reads (18%) | catalogued as rs201441562; called by pindel, varscan2
